HCMI case HCM-BROD-0351-C49 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myomatous Neoplasms; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/082faf22-1925-4478-94da-f124da62cd7e

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1974.

Diagnoses (2)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C49.9; Tissue or organ of origin: Uterus, NOS; Classification of tumor: primary; Age at diagnosis: 42.9 years (15,677 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IV; AJCC pathologic stage: Stage IV; Prior malignancy: yes; Prior treatment: No.
   Recorded as not given: neoadjuvant treatment (type not reported).
2. Metastasis of the uterus (histology not recorded by GDC). ICD-10 code: C79.8; Site of resection or biopsy: Uterus, NOS; Age at diagnosis: 43.9 years (16,018 days); Days to diagnosis: 341 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,174.

Molecular and laboratory tests
- PTEN mutation, nos: Positive.
- TP53 mutation, nos (Targeted Sequencing): Positive; Amino-acid change: M237K.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 48 kg; Height: 158 cm; BMI: 19.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (2 samples)
- Sample HCM-BROD-0351-C49-06B: Sample type: Human Tumor Original Cells; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Human Original Cells; Preservation method: Frozen.
- Sample HCM-BROD-0351-C49-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 12.
